TCGA case TCGA-BQ-5894 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cfc6f9ef-73b1-46af-b4c8-94fdd34f4584

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.5 years (15,510 days); Year of diagnosis: 2010; AJCC clinical T: T3a; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 84 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 11; Lymph nodes tested: 17; Prcc type: Type 2.

Follow-up (1 entry)
- Days to follow up: 84 days; Disease response: With Tumor.

Molecular and laboratory tests
- Platelets: Normal.
- Hemoglobin: Normal.
- Leukocytes: Normal.
- Calcium: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80.7 kg; Height: 159 cm; BMI: 31.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BQ-5894-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.2.
  Slide TCGA-BQ-5894-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-BQ-5894-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-BQ-5894-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BQ-5894-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 0.7; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Tobacco smoking history indicator: 3.
- Follow-up form: Tumor status: With tumor; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 84 days; disease-specific survival: no event (censored), 84 days; progression-free interval: no event (censored), 84 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BQ-5894-01A-11D-1588-01): tumor purity 0.36, ploidy 2.8, whole-genome doublings 1.
